Gene-level copy-number profile of tumor specimen ALCH-B288-TTP1-A from ALCHEMIST case ALCH-B288, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,966 days).
Specimen ALCH-B288-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 347b84ab-ad24-45e8-b677-f6693501fc55.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B288-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/ce88b287-d96b-4022-8a0f-d8387e3495fb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 20,968; copy number 2: 29,075; copy number 3: 6,078; copy number 4: 1,319; copy number 5: 612; copy number 6: 212; copy number 7: 1; copy number 9: 24; copy number 11: 8; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:68,282,388–68,282,622, 1 gene: COX6B1P7.
- chr1:248,548,756–248,635,091, 8 genes (within-gene range 0–3): AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr2:132,256,966–132,263,042, 2 genes (within-gene range 0–2): MIR663B, CDC27P1.
- chr3:72,504,806–72,583,535, 3 genes: AC104435.2, RNU1-62P, AC104435.1.
- chr6:13,264,861–13,328,583, 3 genes (within-gene range 0–2): AL008729.1, TBC1D7, AL008729.2.
- chr6:30,102,897–30,114,724, 2 genes: TRIM31, TRIM31-AS1.
- chr6:73,241,314–73,452,297, 14 genes (within-gene range 0–1): KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS.
- chr7:76,302,673–76,304,295, 1 gene: HSPB1.
- chr8:43,140,464–43,220,809, 2 genes: HGSNAT, VN1R46P.
- chr10:93,059,663–93,077,885, 5 genes: AL358613.1, CYP26C1, AL358613.3, AL358613.2, CYP26A1.
- chr11:55,635,113–55,666,195, 3 genes: OR4P4, OR4S2, OR4C6.
- chr15:28,857,882–28,858,398, 1 gene (within-gene range 0–1): AC174071.1.
- chr16:46,884,362–46,931,289, 1 gene: GPT2.
- chr17:63,917,200–63,932,336, 3 genes (within-gene range 0–2): GH1, AC127029.3, CD79B.
- chr21:7,744,962–9,129,752, 42 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 858 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:14,061–38,402,916, 633 genes, copy number 5–6 (broad region; genes not listed).
- chr10:38,601,418–38,783,108, 8 genes, copy number 5–7: ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr11:112,967–139,612, 3 genes, copy number 5–9 (within-gene range 3–9): AC069287.1, CICP23, LINC01001.
- chr11:1,947,278–1,984,522, 1 gene, copy number 26 (within-gene range 2–26): MRPL23.
- chr11:1,991,096–2,001,470, 5 genes, copy number 6: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr14:29,576,479–42,989,483, 198 genes, copy number 6–9 (broad region; genes not listed).
- chr16:32,715,931–32,788,944, 8 genes, copy number 11: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr22:18,873,543–18,894,407, 2 genes, copy number 6: FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 20,487. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
